FM case AD12082 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/1a119c9a-1768-4df2-bb96-992f3be5a4ff

Female, 60.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the colon; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
